Somatic mutation profile of tumor specimen MP2PRT-PAVSYM-TMP1-A (aliquot MP2PRT-PAVSYM-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVSYM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,229 days).
Specimen MP2PRT-PAVSYM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 876ff2fc-dc88-4a37-a9b6-a5ae28a4166f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSYM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSYM-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9efce063-4456-4bb9-9912-66f900e22dab

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, In Frame Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUBN | c.1942C>G p.L648V | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.936); catalogued as COSV100912952; called by muse, mutect2
- DCAF8L2 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101446169; called by muse, mutect2
- HECW1 | c.4562G>A p.R1521H | Missense Mutation (SNP) | VAF 45/641 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs756422420, COSV67837695; called by muse, mutect2
- KCND3 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 33/642 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs1189045685, COSV56183901; called by muse, mutect2
- SEC14L5 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 49/711 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs373434753; called by muse, mutect2
- ARHGAP21 | c.1724G>C p.R575T | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, varscan2
- IGHV3-53 | c.350delinsGGGGAC | In Frame Ins (INS) | VAF 16/75 reads (21%) | called by pindel, varscan2*
- KHSRP | c.119_120insACCCTC p.R40_G41insPS | In Frame Ins (INS) | VAF 50/183 reads (27%) | called by mutect2, pindel, varscan2
- KIF12 | c.1838T>A p.L613Q (on ENST00000640217; = p.L475Q on NM_138424.1) | Missense Mutation (SNP) | VAF 40/612 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.134); called by muse, mutect2
- PDZRN3 | c.2157G>C p.W719C | Missense Mutation (SNP) | VAF 32/485 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGHV1-45 | c.353delinsCC p.*118S | Silent (INS) | VAF 24/116 reads (21%) | called by pindel, varscan2*
- KIAA1549 | c.5838G>A p.Q1946= (on ENST00000422774 / NM_001164665.2; = p.Q1930= on NM_020910.3) | Silent (SNP) | VAF 24/613 reads (4%) | called by muse, mutect2
- NOTCH3 | c.6570G>A p.A2190= | Silent (SNP) | VAF 126/825 reads (15%) | catalogued as rs771107661, COSV99659562; called by muse, mutect2, varscan2
- PCDHA5 | c.297G>A p.A99= | Silent (SNP) | VAF 44/662 reads (7%) | catalogued as rs950776506; called by muse, mutect2
